Surgical pathology report (de-identified scan), TCGA case TCGA-12-3650, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-3650-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

TCGA-12-3650

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] is a [REDACTED]. In [REDACTED] he was working with the volunteer firefighters and had an [REDACTED]. He apparently had [REDACTED]. An MRI scan was performed. A second scan was performed in [REDACTED].

[REDACTED] Intervals increased in size enhancing left temporoparietal lesion, with maximal transaxial dimensions of approximately 2.3 x 2.2 cm, previously 1.4 x 1.4 cm. New central necrosis versus hemorrhage. Stable or slightly increased secondary rim of cloudlike enhancement about the primary enhancing lesion. Stable local mass effect but no significant midline shift.

GROSS EXAMINATION:

A. "Brain tissue (AF1)". Received fresh for frozen section is a 2.6 x 1.7 x 1 cm portion of soft pink-tan tissue with diffuse erythema. The specimen is partially frozen as representative AF1 and frozen section remnant submitted in block A1. Additional representative sections submitted in blocks A2-3 (approximately 75% specimen submitted).

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioblastoma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular changes and pseudopalisading necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (82% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - AMPLIFICATION (93% OF TUMOR CELLS EXHIBIT AMPLIFICATION)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (61% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (71% OF TUMOR CELLS EXHIBIT LOSS)

[page 2 of 2]
9p21 - LOSS (80% OF TUMOR CELLS EXHIBIT LOSS)

CHROMOSOME 9 CENTROMERE - CENTROMERE LOSS (54% OF TUMOR CELLS EXHIBIT LOSS)

4 OF 4 ABNORMAL MARKERS AND 9P21 EXHIBITS LOSS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED])

LEUCOCYTE COMMON ANTIGEN (LCA): 10% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - NEGATIVE (5% OF TUMOR CELLS)

EGFR wt - POSITIVE (2-3+ IN 70% OF TUMOR CELLS)

EGFR vIII - POSITIVE (2+ IN 20% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 60% OF TUMOR CELLS)

S6 - NEGATIVE (2+ IN 5% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 20% OF TUMOR CELLS)

MAPK - POSITIVE (3+ IN 30% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD: [REDACTED]

Source: NCI Genomic Data Commons file 4dcc1f9a-8cfd-4a28-8b95-02cf37a35834 (TCGA-12-3650.2A696AD0-69A3-435C-B4A4-C3CEB5FE28A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).